Somatic mutation profile of tumor specimen TCGA-Z6-A8JE-01A (aliquot TCGA-Z6-A8JE-01A-11D-A37C-09) from TCGA case TCGA-Z6-A8JE, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 57.1 years (20,855 days).
Specimen TCGA-Z6-A8JE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec4c1bdf-f1d2-49e0-80df-656ae0800c09.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Z6-A8JE-10A (Blood Derived Normal), aliquot TCGA-Z6-A8JE-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d37b37f-b27f-4d23-8af6-c0ae3d45109a

The open-access MAF lists 171 somatic variants for this specimen: 143 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 26, Nonsense Mutation 9, In Frame Del 2, Frame Shift Ins 2, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS12 | c.1574G>A p.R525H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as rs776730549, CM104181, COSV58561688; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 58/82 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TUBA1A | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.934); catalogued as rs1565626872, CM145638, COSV55498842; ClinVar: pathogenic; called by muse, varscan2
- AC011448.1 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1025815225, COSV53063705, COSV99389240; called by muse, mutect2, varscan2
- AKAP6 | c.4662G>C p.Q1554H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV55217088; called by muse, mutect2, varscan2
- BPIFB4 | c.1264A>G p.M422V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100971517; called by muse, mutect2
- CCDC73 | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58798853; called by muse, mutect2, varscan2
- CD7 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1429746468, COSV57067528; called by muse, mutect2, varscan2
- CEP170 | c.4064T>G p.V1355G | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60507842; called by muse, mutect2, varscan2
- CFHR2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.019); catalogued as rs370528458, COSV66381914; called by muse, mutect2, varscan2
- COLEC12 | c.1840T>A p.F614I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV68373157; called by muse, mutect2, varscan2
- DNAJC12 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.711); catalogued as COSV56549549; called by muse, mutect2
- FLNB | c.1539C>G p.F513L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs764967982, COSV55879328; called by muse, mutect2, varscan2
- GAREM1 | c.506A>G p.K169R | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.111); catalogued as rs1461353553; called by muse, mutect2, varscan2
- GCC2 | c.148+1G>A p.X50_splice | Splice Site (SNP) | VAF 56/124 reads (45%) | catalogued as COSV59179498; called by muse, mutect2, varscan2
- GLUL | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV59382982; called by muse, mutect2, varscan2
- HYDIN | c.12553G>A p.E4185K | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as rs750919238, COSV66638327; called by muse, mutect2, varscan2
- IPO5 | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV55160843; called by muse, mutect2, varscan2
- KCNA3 | c.1546C>T p.R516* | Nonsense Mutation (SNP) | VAF 17/28 reads (61%) | catalogued as rs1258043461, COSV63901492; called by muse, mutect2, varscan2
- KCNQ3 | c.2467G>T p.G823W | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV66473767; called by muse, mutect2, varscan2
- KDM4D | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as rs1555099398, COSV58634620; called by muse, mutect2, varscan2
- KHDRBS3 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.844); catalogued as rs749251634; called by muse, mutect2, varscan2
- KIF26B | c.3616C>T p.R1206C | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs777110547; called by muse, mutect2, varscan2
- KLHL2 | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs751575614; called by muse, mutect2, varscan2
- LACC1 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs750807129; called by muse, mutect2, varscan2
- LAMA5 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780029947, COSV53357888; called by muse, mutect2, varscan2
- LRFN5 | c.1193C>G p.S398* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99985359; called by muse, mutect2, varscan2
- MAGEB2 | c.92C>G p.T31S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as COSV66782270; called by muse, mutect2, varscan2
- MAPK10 | c.985G>A p.E329K (on ENST00000359221 / NM_001351625.2; = p.E367K on NM_002753.5) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as COSV60376282, COSV60395978; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MKKS | c.1263C>G p.I421M | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100726286; called by muse, mutect2, varscan2
- MYORG | c.976C>A p.R326S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.087); catalogued as COSV52627680; called by muse, mutect2
- NDUFC2 | c.99C>G p.I33M | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as rs979563390; called by muse, mutect2, varscan2
- NLRP1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as rs201858694, COSV52570504; called by muse, mutect2, varscan2
- OR2A5 | c.864G>C p.L288F | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV68738614; called by muse, mutect2
- OR5K1 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs771972823, COSV100220856; called by muse, mutect2, varscan2
- PFAS | c.555G>C p.E185D | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV58981876; called by muse, mutect2, varscan2
- PKP1 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.391); catalogued as rs998787266; called by muse, mutect2, varscan2
- POU6F1 | c.1625C>G p.S542C | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100374926; called by muse, mutect2, varscan2
- PPP2R3B | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs1340551534; called by muse, mutect2, varscan2
- PSG4 | c.1139C>G p.S380C | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as COSV54933418, COSV99737488; called by muse, mutect2
- RABEP2 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs757390295; called by muse, mutect2, varscan2
- RANBP17 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV66649790; called by muse, mutect2, varscan2
- RASA1 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV57195111; called by muse, mutect2, varscan2
- RP1L1 | c.6633_6680del p.A2214_E2229del | In Frame Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs762081947; called by muse*, mutect2, pindel
- SCN7A | c.4582G>T p.D1528Y | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV69275164; called by muse, mutect2, varscan2
- SLC38A8 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 83/103 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1233941493; called by muse, mutect2, varscan2
- SOX1 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 35/47 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs896216943; called by muse, mutect2, varscan2
- SPEF2 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 70/114 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as rs755241823, COSV56798971; called by muse, mutect2, varscan2
- SUPT6H | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1388196800; called by muse, mutect2, varscan2
- TMEM132D | c.1488G>C p.M496I | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.647); catalogued as COSV67159259; called by muse, mutect2
- TMEM200C | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs770578061; called by muse, mutect2, varscan2
- TMPO | c.673C>G p.Q225E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100587760; called by muse, mutect2
- TNPO3 | c.2077C>T p.H693Y | Missense Mutation (SNP) | VAF 25/35 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV99602335; called by muse, mutect2, varscan2
- TRAIP | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs748874948; called by muse, mutect2, varscan2
- TSGA10 | c.2060G>T p.R687L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.688); catalogued as rs148460657; called by muse, mutect2, varscan2
- TTN | c.18965C>G p.S6322C (on ENST00000591111; = p.S5395C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | PolyPhen possibly damaging (0.855); catalogued as COSV59969524; called by muse, mutect2, varscan2
- USP54 | c.2096C>G p.P699R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161042; called by muse, mutect2, varscan2
- UVSSA | c.53C>A p.P18H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.87); catalogued as rs960368034; called by muse, mutect2, varscan2
- ZEB1 | c.1278G>T p.R426S | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58050139; called by muse, mutect2, varscan2
- ABCA2 | c.6726G>T p.E2242D (on ENST00000614293; = p.E2212D on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- ACAP2 | c.2180G>A p.R727H | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- ADNP | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AGO2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ANKRD26 | c.1480C>T p.L494F | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANXA5 | c.573A>T p.E191D | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGEF9 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BTBD3 | c.1552C>T p.L518F | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- C19orf57 | c.615G>C p.Q205H | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- CABIN1 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CBLN1 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CDC42BPA | c.988G>C p.G330R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP43 | c.4345C>G p.L1449V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CHRNB4 | c.1032C>A p.F344L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- COL21A1 | c.2407G>T p.A803S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- COL4A6 | c.3854C>G p.S1285C | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CORO7 | c.2566A>G p.S856G | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- CRNN | c.21C>G p.N7K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DCBLD2 | c.2246T>C p.V749A | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ELAPOR2 | c.751A>T p.K251* (on ENST00000450689 / NM_001142749.3; = p.K84* on NM_152748.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 49/76 reads (64%) | called by muse, mutect2, varscan2
- EMB | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ERBIN | c.2943C>A p.Y981* | Nonsense Mutation (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- ERCC1 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ETFDH | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- FBN1 | c.7537C>A p.P2513T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- FMN2 | c.4150C>G p.H1384D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- FNIP1 | c.878A>T p.Q293L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- GABRB1 | c.302G>C p.G101A | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.301); called by muse, mutect2, varscan2
- GABRB1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2
- GPSM1 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GRIP1 | c.1640C>T p.S547F (on ENST00000359742 / NM_001379345.1; = p.S495F on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- H4C13 | c.196G>C p.V66L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HIVEP3 | c.2569G>C p.E857Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HOMEZ | c.1028G>C p.R343T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- HTRA4 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV3-43 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 25/74 reads (34%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2196G>C p.W732C | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA0319 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- KIAA0586 | c.1518C>G p.I506M (on ENST00000619416 / NM_001244190.2; = p.I521M on NM_014749.5) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- KIAA0895 | c.1306G>T p.G436W (on ENST00000297063 / NM_001100425.2; = p.G385W on NM_015314.3) | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KIF26B | c.6278_6283delinsTGA p.A2093_L2095delinsVI | In Frame Del (DEL) | VAF 15/58 reads (26%) | called by pindel, varscan2*
- KMT2E | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2
- LRRC32 | c.1420T>G p.S474A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- LRRK1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- LYRM2 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MBD5 | c.2891C>G p.T964S | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEI1 | c.620C>G p.S207C | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- MROH9 | c.703C>G p.Q235E | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- NOL7 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- NXN | c.1236G>C p.E412D | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR13C2 | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- OTUD4 | c.233A>G p.K78R (on ENST00000447906 / NM_001366057.1; = p.K13R on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- PANK1 | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PASD1 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- PDE3B | c.3079G>A p.D1027N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PDS5B | c.2589C>A p.D863E | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIH1D2 | c.681G>C p.Q227H | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- POTEE | c.272T>C p.M91T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PSG4 | c.722A>T p.K241M | Missense Mutation (SNP) | VAF 43/201 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- RAB39A | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- RBBP7 | c.139C>T p.Q47* | Nonsense Mutation (SNP) | VAF 27/35 reads (77%) | called by muse, mutect2, varscan2
- RHPN1 | c.1340C>G p.S447* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | called by muse, mutect2, varscan2
- RICTOR | c.3515C>T p.T1172I | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.075); called by muse, mutect2
- ROCK2 | c.3913A>G p.M1305V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SAFB | c.2316G>T p.M772I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.878); called by muse, varscan2
- SH3TC1 | c.1245C>G p.D415E | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- SLC38A10 | c.1891C>A p.P631T | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.071); called by muse, mutect2
- SLITRK6 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SMC5 | c.1660T>G p.L554V | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- TAF4 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- TARS1 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TG | c.1997G>C p.R666T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TG | c.6585G>C p.E2195D | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TLE3 | c.1459_1469dup p.C490Wfs*7 | Frame Shift Ins (INS) | VAF 7/29 reads (24%) | called by mutect2, varscan2
- TMCO6 | c.558G>T p.Q186H | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TNFSF13B | c.130G>C p.D44H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- TRAV19 | c.239T>C p.I80T | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TUBA1A | c.1174G>C p.D392H | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); called by muse, varscan2
- WBP2 | c.554dup p.M185Ifs*74 | Frame Shift Ins (INS) | VAF 48/125 reads (38%) | called by mutect2, pindel, varscan2
- ZCWPW1 | c.1113G>T p.W371C | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ZFHX3 | c.8284G>T p.G2762* | Nonsense Mutation (SNP) | VAF 38/47 reads (81%) | called by muse, mutect2, varscan2
- ZNF750 | c.73T>G p.Y25D | Missense Mutation (SNP) | VAF 67/91 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AMPD1 | c.1482G>A p.R494= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs1371202947; called by muse, mutect2, varscan2
- ANK1 | c.1947G>A p.E649= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs375243297; called by muse, mutect2, varscan2
- APOD | c.45C>T p.F15= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs757303997, COSV58401503; called by muse, mutect2, varscan2
- ATG2A | c.5052C>T p.V1684= | Silent (SNP) | VAF 16/60 reads (27%) | called by muse, mutect2, varscan2
- GPRC5B | c.198C>T p.G66= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs775838103, COSV100314870; called by muse, mutect2, varscan2
- GZF1 | c.531C>G p.L177= | Silent (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.1524G>A p.S508= | Silent (SNP) | VAF 23/192 reads (12%) | catalogued as rs747627986, COSV54825292; called by muse, mutect2, varscan2
- LBX2 | c.528C>G p.L176= (on ENST00000377566 / NM_001282430.2; = p.L172= on NM_001009812.2) | Silent (SNP) | VAF 86/130 reads (66%) | called by muse, mutect2, varscan2
- LTBP4 | c.789G>T p.A263= (on ENST00000308370 / NM_001042544.1; = p.A226= on NM_003573.2) | Silent (SNP) | VAF 23/63 reads (37%) | called by muse, mutect2, varscan2
- MAGEC1 | c.3010C>T p.L1004= | Silent (SNP) | VAF 32/40 reads (80%) | catalogued as COSV53572735; called by muse, mutect2, varscan2
- MLLT6 | c.2169G>C p.L723= | Silent (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- MORC3 | c.72T>C p.T24= | Silent (SNP) | VAF 43/66 reads (65%) | called by muse, mutect2, varscan2
- NDUFA11 | c.9G>A p.P3= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as rs576231769; called by muse, mutect2, varscan2
- PCDH12 | c.2748C>G p.L916= | Silent (SNP) | VAF 63/89 reads (71%) | called by muse, mutect2, varscan2
- PDCD1 | c.108C>T p.T36= | Silent (SNP) | VAF 39/58 reads (67%) | called by muse, mutect2, varscan2
- PKHD1 | c.5823A>G p.Q1941= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV61889601; called by muse, mutect2, varscan2
- PMS1 | c.270C>T p.Y90= | Silent (SNP) | VAF 13/68 reads (19%) | catalogued as rs149723996; called by muse, mutect2, varscan2
- PRR19 | c.669A>T p.P223= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- PTPRH | c.2562G>T p.L854= | Silent (SNP) | VAF 28/63 reads (44%) | catalogued as rs1189194634; called by muse, mutect2, varscan2
- SLC44A3 | c.315C>G p.V105= (on ENST00000271227 / NM_001114106.3; = p.V57= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- TBC1D9B | c.3666C>T p.D1222= (on ENST00000356834 / NM_198868.3; = p.D1205= on NM_015043.4) | Silent (SNP) | VAF 35/46 reads (76%) | called by muse, mutect2, varscan2
- TCEA2 | c.132C>G p.L44= | Silent (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- TIMELESS | c.3141C>T p.L1047= | Silent (SNP) | VAF 17/90 reads (19%) | called by muse, mutect2, varscan2
- TRANK1 | c.7167C>T p.F2389= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV57143897; called by muse, mutect2, varscan2
- USP43 | c.183C>T p.F61= | Silent (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- UTRN | c.4582C>T p.L1528= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs778079117, COSV62348454; called by muse, mutect2, varscan2
- HTR2C | c.350-24491G>T | Intron (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- SNORD3B-1 | n.211G>A | RNA (SNP) | VAF 8/26 reads (31%) | catalogued as rs770265522; called by mutect2, varscan2
